Somatic mutation profile of tumor specimen TCGA-16-0850-01A (aliquot TCGA-16-0850-01A-01W-0424-08) from TCGA case TCGA-16-0850, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.8 years (19,281 days).
Specimen TCGA-16-0850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c266af3-0e61-4cd3-943e-241a73869c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-16-0850-10A (Blood Derived Normal), aliquot TCGA-16-0850-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8510831-55df-4406-864f-7c9b5281fea8

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 447/744 reads (60%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RP2 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 81/185 reads (44%) | catalogued as rs104894927, CM991106, COSV54463407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 950/980 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC025165.3 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 719/3697 reads (19%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.81); catalogued as rs139487489; called by muse, mutect2, varscan2
- ADAM23 | c.1198A>T p.S400C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100008586; called by muse, mutect2, varscan2
- ADAMTS12 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 152/397 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375250179; called by muse, mutect2, varscan2
- ALKBH2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 170/494 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371845082; called by muse, mutect2, varscan2
- ATP4A | c.3034G>C p.V1012L | Missense Mutation (SNP) | VAF 132/239 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV99382983; called by muse, mutect2, varscan2
- CA12 | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV99458675; called by muse, mutect2, varscan2
- CAND1 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs757831604, COSV101598287; called by muse, mutect2, varscan2
- CUL4B | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 147/563 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341087; called by muse, mutect2, varscan2
- DGAT2 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 96/342 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs745315498, COSV57175468; called by muse, mutect2, varscan2
- DNAJC22 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs755703056, COSV101222595; called by muse, mutect2, varscan2
- DUSP9 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV100720167; called by muse, varscan2
- FAT4 | c.5432C>A p.S1811* | Nonsense Mutation (SNP) | VAF 8/242 reads (3%) | catalogued as COSV58678066; called by muse, mutect2
- HGSNAT | c.1170G>A p.W390* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV52818239, COSV99925465; called by muse, mutect2, varscan2
- HOXA10 | c.507C>G p.Y169* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99385667; called by muse, mutect2, varscan2
- IFNA7 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 160/708 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV99497576; called by muse, mutect2, varscan2
- IGSF3 | c.1069A>G p.S357G | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1372553988, COSV100605042; called by muse, varscan2
- ISM2 | c.1098C>A p.D366E (on ENST00000342219 / NM_199296.3; = p.T251N on NM_182509.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV99376850; called by muse, mutect2, varscan2
- KDM2B | c.2221T>C p.S741P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV100997631; called by muse, mutect2
- KLHDC8A | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 177/908 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1407419732, COSV100903770, COSV65678735; called by muse, mutect2, varscan2
- KPRP | c.1195T>C p.C399R | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100908776; called by muse, mutect2
- KRT19 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371064123; called by muse, mutect2, varscan2
- LILRB2 | c.35-1G>A p.X12_splice | Splice Site (SNP) | VAF 29/46 reads (63%) | catalogued as COSV58745503; called by muse, mutect2, varscan2
- LPP | c.1711-1G>A p.X571_splice | Splice Site (SNP) | VAF 62/343 reads (18%) | catalogued as COSV100448134; called by muse, mutect2, varscan2
- NBPF26 | c.1901C>T p.A634V (on ENST00000620612; = p.A372V on NM_001351372.1) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs1432026115; called by mutect2, varscan2
- NCR1 | c.636C>A p.G212= | Splice Region (SNP) | VAF 517/891 reads (58%) | catalogued as rs770811879, COSV52555460, COSV99401131; called by muse, mutect2, varscan2
- OTX1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV99246455; called by muse, mutect2
- PCDHA3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.435); catalogued as COSV100793689; called by muse, mutect2, varscan2
- PDE6B | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377243929; called by muse, varscan2
- PIK3R4 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 108/557 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs769533810, COSV63240300; called by muse, mutect2, varscan2
- RABGAP1 | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV100438665; called by muse, mutect2, varscan2
- RIPOR1 | c.163G>A p.A55T (on ENST00000379312 / NM_001193522.2; = p.A51T on NM_024519.4) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs113573319, COSV50267563; called by muse, mutect2, varscan2
- RPGRIP1L | c.3284A>C p.N1095T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100046702; called by muse, mutect2, varscan2
- RTN4IP1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.847); catalogued as rs962250841, COSV100954227; called by muse, mutect2, varscan2
- SEMA5A | c.2435A>G p.N812S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs762410791, COSV101228669; called by muse, mutect2, varscan2
- SHMT1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 26/634 reads (4%) | catalogued as COSV100363646; called by muse, mutect2
- SPG11 | c.2849del p.L950Wfs*13 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as CD166713; called by pindel, varscan2
- TCHHL1 | c.1563C>A p.D521E | Missense Mutation (SNP) | VAF 119/546 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100916595; called by muse, mutect2, varscan2
- UGT2B4 | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936696704, COSV100522607, COSV59318157, COSV59321077; called by muse, mutect2, varscan2
- VEGFC | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 125/545 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs766231656, COSV99710241; called by muse, mutect2, varscan2
- MAGEB6B | c.899A>T p.N300I | Missense Mutation (SNP) | VAF 203/436 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF6 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- A1CF | c.1515C>A p.A505= (on ENST00000373993 / NM_138932.2; = p.A497= on NM_014576.4) | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99257434; called by muse, mutect2, varscan2
- CD226 | c.915T>C p.S305= | Silent (SNP) | VAF 58/239 reads (24%) | catalogued as rs1371446066, COSV99711461; called by muse, mutect2
- CFH | c.2022T>C p.V674= | Silent (SNP) | VAF 88/374 reads (24%) | catalogued as COSV100810065; called by muse, mutect2, varscan2
- CYP27B1 | c.33G>A p.V11= | Silent (SNP) | VAF 73/2908 reads (3%) | catalogued as COSV99141636; called by muse, mutect2
- DNAH11 | c.3465C>T p.S1155= | Silent (SNP) | VAF 182/787 reads (23%) | catalogued as rs755144481, COSV100180464; called by muse, mutect2, varscan2
- IL21R | c.12C>G p.G4= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV100560472; called by muse, mutect2, varscan2
- KIAA1109 | c.2457T>G p.V819= | Silent (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2
- MAGEE1 | c.1107G>A p.P369= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV63912055; called by muse, mutect2
- MMP11 | c.1218G>A p.R406= | Silent (SNP) | VAF 56/241 reads (23%) | catalogued as COSV99303336; called by muse, mutect2, varscan2
- PKHD1 | c.7023T>C p.Y2341= | Silent (SNP) | VAF 71/335 reads (21%) | catalogued as COSV100584322; called by muse, mutect2, varscan2
- POLR3E | c.1695C>T p.F565= | Silent (SNP) | VAF 60/96 reads (63%) | catalogued as rs1339568375, COSV100242001, COSV100242359; called by muse, mutect2, varscan2
- RGS3 | c.1455C>T p.Y485= (on ENST00000350696 / NM_001282923.2; = p.Y373= on NM_017790.4) | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100465817; called by muse, mutect2, varscan2
- TCEAL3 | c.219A>G p.E73= | Silent (SNP) | VAF 246/592 reads (42%) | catalogued as COSV99685327; called by mutect2, varscan2
- TRIML2 | c.1194C>T p.C398= | Silent (SNP) | VAF 68/278 reads (24%) | catalogued as rs769523346, COSV58714591; called by muse, mutect2, varscan2
